Somatic mutation profile of tumor specimen 0DP48C from CCDI case PBCDCR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.9 years (3,257 days).
Specimen 0DP48C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67b4c4fb-c721-45b3-8c6a-72d53ca6f831.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP46X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88aa6982-d742-46d4-87f2-6cfa1efa7751

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 905/2203 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCDC22 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 52/872 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs199545573, COSV59903756; ClinVar: uncertain significance; called by muse, mutect2
- PTPRH | c.2647C>T p.L883F | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV54743085; called by muse, mutect2
- VSIG10L | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 28/792 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1379812689; called by muse, mutect2
- BCORL1 | c.4751A>G p.D1584G | Missense Mutation (SNP) | VAF 197/1524 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SSR2 | c.364A>T p.I122F | Missense Mutation (SNP) | VAF 46/1471 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- HEATR5B | c.5688C>T p.C1896= | Silent (SNP) | VAF 99/1382 reads (7%) | catalogued as rs781501617; called by muse, mutect2
- ZSWIM3 | c.1452G>A p.Q484= | Silent (SNP) | VAF 42/831 reads (5%) | called by muse, mutect2
- ANKRD27 | c.526-31G>A | Intron (SNP) | VAF 28/235 reads (12%) | catalogued as rs749645368; called by muse, mutect2, varscan2
- DUXA | c.*15A>C | 3'UTR (SNP) | VAF 48/1435 reads (3%) | called by muse, mutect2
- FAM50A | c.297-47G>T | Intron (SNP) | VAF 52/610 reads (9%) | called by muse, mutect2
- PCK1 | c.611-40G>A | Intron (SNP) | VAF 34/463 reads (7%) | catalogued as rs767046921; called by muse, mutect2
